Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3894, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3894-01A (Primary Tumor).

Diagnosis:

In Block A, this is a characteristic moderately differentiated adenocarcinoma of the colon (here a rectal carcinoma) with infiltration especially of the muscularis and the adjoining fatty connective tissue, thus pT3, with vascular infiltrates, thus L1, V1.

Tumor classification:

ICDO-DA M8140/3

G2

pT3, L1, V1, pN0 (0 of 15), locally R0

Source: NCI Genomic Data Commons file c7ff9b92-7578-45b1-bb94-fb93e1ad8360 (TCGA-AG-3894.8B5EDD97-6CAF-46E8-BCF1-66D57BBA97DF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).